Somatic mutation profile of tumor specimen C3N-00846-02 (aliquot CPT0024810009) from CPTAC case C3N-00846, project CPTAC-3 (Other and unspecified parts of tongue — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 67.4 years (24,608 days).
Specimen C3N-00846-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc80300e-901a-4132-a0b5-ebfff8124f3a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00846-71 (Blood Derived Normal), aliquot CPT0024890002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf873d8b-4808-4f70-aaa7-02c3c13c3338

The open-access MAF lists 88 somatic variants for this specimen: 63 protein-altering or splice-affecting, 14 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 14, Intron 8, RNA 2, Frame Shift Ins 2, Nonsense Mutation 2, Splice Site 2, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.151-1G>A p.X51_splice | Splice Site (SNP) | VAF 53/477 reads (11%) | hotspot (GDC flag); catalogued as CS014428, CS067079, COSV58682903, COSV58695350, COSV58708670, COSV58717973; called by muse, mutect2, varscan2
- TP53 | c.856G>C p.E286Q | Missense Mutation (SNP) | VAF 54/754 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs786201059, CM076567, CM1212545, COSV52664318, COSV52687201, COSV52688214; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 36/562 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- CASP8 | c.722A>G p.N241S (on ENST00000432109 / NM_033355.3; = p.N258S on NM_001228.4) | Missense Mutation (SNP) | VAF 34/379 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1360228191, COSV51852774, COSV51853857; called by muse, mutect2
- CLEC4C | c.206C>T p.T69I | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs920948779, COSV63582400; called by muse, mutect2, varscan2
- DCUN1D3 | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 45/478 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as COSV60952315; called by muse, mutect2
- ELAC2 | c.2024G>A p.R675Q | Missense Mutation (SNP) | VAF 37/583 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765368974; ClinVar: uncertain significance; called by muse, mutect2
- EPM2AIP1 | c.644C>G p.T215S | Missense Mutation (SNP) | VAF 34/369 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.445); catalogued as rs753228034; called by muse, mutect2
- EXOSC9 | c.1117A>G p.M373V | Missense Mutation (SNP) | VAF 11/155 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs763519680; called by muse, mutect2
- FAT1 | c.1882C>T p.R628* | Nonsense Mutation (SNP) | VAF 19/312 reads (6%) | catalogued as rs766787268, COSV71671712; called by muse, mutect2
- FOXRED2 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 29/343 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as rs1268967073; called by muse, mutect2
- H3C4 | c.358A>G p.I120V | Missense Mutation (SNP) | VAF 35/518 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as rs142670361; called by muse, mutect2
- HSD17B12 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 28/285 reads (10%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as rs771325924; called by muse, mutect2
- IGKV1D-43 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 22/382 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs368187966; called by muse, mutect2
- LZTS3 | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 24/277 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1282850411; called by muse, mutect2
- MEGF8 | c.828G>A p.P276= | Splice Region (SNP) | VAF 8/128 reads (6%) | catalogued as rs1191346025; called by muse, mutect2
- NOTCH3 | c.835C>T p.Q279* | Nonsense Mutation (SNP) | VAF 77/587 reads (13%) | catalogued as COSV54626632; called by muse, mutect2, varscan2
- OSCAR | c.222C>G p.I74M | Missense Mutation (SNP) | VAF 32/571 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as rs1414602729; called by muse, mutect2
- PRKCE | c.794G>T p.G265V | Missense Mutation (SNP) | VAF 14/163 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100078714; called by muse, mutect2
- RCC2 | c.898C>T p.R300W | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64905460; called by muse, mutect2
- SH3GL1 | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 60/586 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs201867179, COSV53656807; called by muse, mutect2
- SLC25A53 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1465715866; called by mutect2, varscan2
- SLC6A13 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 14/201 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758728968, COSV58260973; called by muse, mutect2
- SYNE2 | c.15253G>A p.V5085M | Missense Mutation (SNP) | VAF 22/271 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs144471413; ClinVar: benign; called by muse, mutect2
- TP53 | c.855G>T p.E285D | Missense Mutation (SNP) | VAF 55/756 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); catalogued as COSV52933457, COSV52950642; called by muse, mutect2
- WDR6 | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 24/286 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs758898780, COSV58245108; called by muse, mutect2
- ZNF226 | c.527C>G p.T176R | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV100335125; called by muse, mutect2
- AASDH | c.1945A>T p.S649C | Missense Mutation (SNP) | VAF 22/227 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); called by muse, mutect2
- ADGRV1 | c.6356C>A p.T2119N | Missense Mutation (SNP) | VAF 15/293 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, mutect2
- AGTPBP1 | c.3562A>G p.S1188G (on ENST00000357081 / NM_001330701.2; = p.S1148G on NM_015239.2) | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); called by muse, mutect2
- AKAP11 | c.4550A>G p.N1517S | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- ALDH1A2 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 25/469 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- AOX1 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2
- ARHGAP40 | c.1508G>C p.R503T | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); called by muse, mutect2
- CCAR1 | c.2779A>T p.M927L | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.558); called by muse, mutect2
- CCDC14 | c.760A>C p.N254H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | called by muse, mutect2, varscan2
- CDC20 | c.791T>C p.M264T | Missense Mutation (SNP) | VAF 18/359 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CDH23 | c.3019G>A p.D1007N | Missense Mutation (SNP) | VAF 28/364 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- DNAH10 | c.6409G>C p.A2137P (on ENST00000409039; = p.A2076P on NM_207437.3) | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2
- EPS8 | c.1960A>G p.I654V | Missense Mutation (SNP) | VAF 28/437 reads (6%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2
- FAT1 | c.2330dup p.L777Ffs*5 | Frame Shift Ins (INS) | VAF 16/186 reads (9%) | called by mutect2, pindel
- FOXH1 | c.329T>G p.V110G | Missense Mutation (SNP) | VAF 18/680 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- GOLGB1 | c.4673C>G p.S1558C | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- GPR174 | c.451C>G p.L151V | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- GSTO2 | c.671A>T p.Q224L | Missense Mutation (SNP) | VAF 30/310 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2
- HIPK1 | c.1481T>G p.L494R | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- IQGAP3 | c.3490G>A p.D1164N | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2
- KDM3B | c.4987dup p.Y1663Lfs*2 | Frame Shift Ins (INS) | VAF 28/288 reads (10%) | called by mutect2, pindel
- LIG1 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); called by muse, mutect2
- MAPKBP1 | c.1589C>G p.S530C (on ENST00000456763 / NM_001128608.2; = p.S524C on NM_014994.3) | Missense Mutation (SNP) | VAF 13/193 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NAP1L1 | c.1044A>T p.E348D | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.899); called by muse, mutect2
- NEO1 | c.2945A>T p.E982V | Missense Mutation (SNP) | VAF 10/193 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- NPAP1 | c.1564G>T p.D522Y | Missense Mutation (SNP) | VAF 14/296 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2
- PIK3C2G | c.3673C>T p.P1225S (on ENST00000676171; = p.P1184S on NM_004570.5) | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2
- PRICKLE2 | c.1948A>C p.N650H (on ENST00000295902; = p.N594H on NM_198859.4) | Missense Mutation (SNP) | VAF 29/327 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PZP | c.3874T>A p.F1292I | Missense Mutation (SNP) | VAF 27/316 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- RREB1 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2
- TCFL5 | c.1246A>G p.I416V | Missense Mutation (SNP) | VAF 15/214 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- TRIM37 | c.2812+2T>C p.X938_splice | Splice Site (SNP) | VAF 25/295 reads (8%) | called by muse, mutect2
- TULP4 | c.4057A>G p.I1353V | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.005); called by muse, mutect2
- ZFX | c.102A>T p.E34D | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ZNF518B | c.1376C>T p.T459I | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ZNF721 | c.409T>C p.Y137H (on ENST00000338977; = p.Y149H on NM_133474.4) | Missense Mutation (SNP) | VAF 12/264 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.146); called by muse, mutect2
- CSMD3 | c.5421C>T p.F1807= (on ENST00000297405 / NM_001363185.1; = p.F1703= on NM_052900.3) | Silent (SNP) | VAF 54/387 reads (14%) | called by muse, mutect2, varscan2
- DENND2B | c.36C>T p.T12= | Silent (SNP) | VAF 24/277 reads (9%) | catalogued as rs773972689; called by muse, mutect2
- FNIP1 | c.504C>G p.G168= | Silent (SNP) | VAF 12/282 reads (4%) | called by muse, mutect2
- HSPA1A | c.27C>T p.I9= | Silent (SNP) | VAF 23/425 reads (5%) | called by muse, mutect2
- MBNL2 | c.1077C>T p.Y359= (on ENST00000376673 / NM_001382666.1; = p.Y347= on NM_207304.3 and 13 other RefSeq transcripts) | Silent (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- MUC6 | c.2331C>T p.S777= | Silent (SNP) | VAF 24/269 reads (9%) | catalogued as rs772618738; called by muse, mutect2
- MYH1 | c.5604C>G p.L1868= | Silent (SNP) | VAF 18/246 reads (7%) | called by muse, mutect2
- MYH4 | c.1143G>A p.T381= | Silent (SNP) | VAF 11/113 reads (10%) | catalogued as rs1458185288, COSV55114336, COSV55123768; called by muse, mutect2
- NAALADL2 | c.372C>T p.H124= | Silent (SNP) | VAF 21/362 reads (6%) | catalogued as rs993923083, COSV70795021; called by muse, mutect2
- P3H1 | c.1425C>T p.D475= | Silent (SNP) | VAF 48/582 reads (8%) | catalogued as rs373467876; ClinVar: likely benign; called by muse, mutect2
- PCF11 | c.51C>T p.D17= | Silent (SNP) | VAF 16/252 reads (6%) | called by muse, mutect2
- PEX5L | c.1623C>T p.F541= | Silent (SNP) | VAF 22/203 reads (11%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.1491G>C p.A497= (on ENST00000265814 / NM_001198628.1; = p.A470= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/140 reads (10%) | called by muse, mutect2
- TMEM184B | c.1119G>A p.G373= | Silent (SNP) | VAF 22/277 reads (8%) | called by muse, mutect2
- AKAP17A | c.1152+25C>T | Intron (SNP) | VAF 38/406 reads (9%) | catalogued as rs774253437; called by muse, mutect2
- ARPP19P2 | n.205A>T | RNA (SNP) | VAF 14/278 reads (5%) | called by muse, mutect2
- BID | c.362-633C>T | Intron (SNP) | VAF 23/403 reads (6%) | catalogued as rs763414907, COSV58007265; called by muse, mutect2
- CUL7 | c.2398-52dup | Intron (INS) | VAF 15/162 reads (9%) | called by mutect2, pindel
- FLCN | c.396+120C>T | Intron (SNP) | VAF 16/284 reads (6%) | called by muse, mutect2
- HSPD1 | c.428-34A>G | Intron (SNP) | VAF 12/138 reads (9%) | called by muse, mutect2
- PDLIM2 | c.541-20C>T | Intron (SNP) | VAF 29/395 reads (7%) | catalogued as rs1252796684; called by muse, mutect2
- RDH10 | c.770+735A>T | Intron (SNP) | VAF 19/202 reads (9%) | called by muse, mutect2
- SDHAP1 | n.1043C>G | RNA (SNP) | VAF 25/800 reads (3%) | called by muse, mutect2
- SLC39A13 | c.735+168C>T | Intron (SNP) | VAF 17/424 reads (4%) | catalogued as rs1218126087; called by muse, mutect2
- VSIR | c.-68T>A | 5'UTR (SNP) | VAF 9/175 reads (5%) | called by muse, mutect2
